CCDI case PBCBVP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a6d8761c-1a23-4454-a002-ac8a1cb2caa6

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Subependymal giant cell astrocytoma: ICD-O-3 morphology code: 9384/1; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 12.2 years (4,448 days).

Biospecimens (2 samples)
- Sample 0DPL7F: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPL7N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
